Surgical pathology report (de-identified scan), TCGA case TCGA-MT-A51X, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Minnesota, specimen TCGA-MT-A51X-01A (Primary Tumor).

[page 1 of 14]
SPECIMEN(S):

A: Anterior midline

B: Left lateral

C: Medial mucosa

D: Right hemiglossectomy

E: Posterior deep margin

F: Posterior mucosa

G: Right gingival margin

H: Right superficial lymph node

I: Right level 3

J: Right zone 3

K: Right level 2 neck dissection

L: Right zone 2A

M: 2A/2B junction

N: Right zone 2

O: Right zone 3

P: PET positive left zone 3 lymph node

Q: Left JD lymph node

R: Right level 1B

S: Level 1A and 1B

LED-0-3

Carcinoma, squamous cell
Keratinizing 8071/3
Site: Tongue NOS 02.9
by 2/15/13

[page 2 of 14]
FINAL DIAGNOSIS:

D. Tongue, right, hemiglossectomy

- Keratinizing well-differentiated squamous cell carcinoma
- Tumor measures 2 cm at its greatest dimension
- No perineural or lymphatic invasion
- Margins negative but close for invasive carcinoma (tumor less than less than 0.1 cm from the lateral and medial margins, and 0.2 cm from anterior margin)
- Foci of high grade adjacent to invasive carcinoma, not present at resection margins
- See microscopic for tumor checklist

K. Lymph node, zone 2, excision

- Metastatic squamous carcinoma in one of two lymph nodes (1/2)
- Metastatic focus measures 6 mm in greatest dimension
- No extracapsular extension

L. Lymph node, right zone 2A, excision

- Metastatic squamous carcinoma in one of two lymph nodes (1/2)
- Metastatic focus measures 8 mm in greatest dimension
- No extracapsular extension

A. Tongue, "anterior midline," biopsy (including AFS1)

- No evidence of dysplasia or invasive carcinoma

[page 3 of 14]
B. Tongue, "left lateral" biopsy (including BFS1)

- No evidence of dysplasia or invasive carcinoma

C. Oral cavity, "medial mucosa4 biopsy (including CFS1)

- No evidence of dysplasia or invasive carcinoma

E. Tongue, "posterior deep margin", biopsy (including EFS1)

- No evidence of dysplasia or invasive carcinoma

F. Oral cavity, "posterior mucosa," biopsy (including FFS1)

- No evidence of dysplasia or invasive carcinoma

G. Oral cavity, "right gingival margin," biopsy (including GFS1)

- No evidence of dysplasia or invasive carcinoma

H. Lymph node, right superficial, excision (including HFS1)

- One lymph node with no evidence of malignancy (0/1)

I. Lymph node, level 3, excision (including IFS1)

- One lymph node with no evidence of malignancy (0/1)

J. Lymph node, zone 3, excision

- Fibrofatty tissue with no evidence of malignancy
- No lymph nodes identified

[page 4 of 14]
M. Lymph node, junction 2A/2B, (including MFS1)

- One lymph node with no evidence of malignancy (0/1)

N. Lymph node, right zone 2, excision

- Eleven lymph nodes with no evidence of malignancy (0/11)

O. Lymph node, right zone 3, excision

- Five lymph nodes with no evidence of malignancy (0/5)

P. Lymph node, left zone 3, (including PFS1)

- One lymph node with no evidence of malignancy (0/1)

Q. Lymph node, left JD, (including QFS1)

- Three lymph nodes with no evidence of malignancy (0/3)

R. Lymph node, right level 1B, excision

- One lymph node with no evidence of malignancy (0/1)

S. Lymph node, left 1A/1B, excision

- Seven lymph nodes with no evidence of malignancy (0/7)

CLINICAL HISTORY:

The patient is a year-old man with right tongue cancer. Operative

Procedure: Right hemiglossectomy.

[page 5 of 14]
GROSS:

Nineteen containers are received, each labeled.

- A. The first container is designated "anterior midline." The specimen consists of a red 0.7 x 0.5 x 0.5 cm tissue fragment entirely submitted for frozen section as A1FS.

- B. The next container is designated "left lateral." The specimen consists of a red 2.0 x 0.6 x 0.3 cm tissue fragment entirely submitted for frozen section as B1FS.

- C. The next container is designated "medial mucosa." The specimen consists of a pink-tan strip measuring 2.2 x 0.4 x 0.2 cm entirely submitted for frozen section as C1FS.

- D. The next container is designated "right hemiglossectomy, stitch anterior." The specimen consists of a right hemiglossectomy with a stitch designating the anterior orientation. The specimen measures 5.0 cm from anterior to posterior, 3.5 cm from superior to inferior, and 2.7 cm from medial to lateral. Mucosal surfaces of the tongue are pink-tan and finely granular. There is a nodular bulge in the right anterolateral aspect of the specimen measuring 2.0 cm in greatest dimension. The specimen is inked as follows: anterior orange, posterior black, medial green, lateral yellow, inferior red (deep). The specimen is coronally sectioning beginning at the anterior margin and ending at

[page 6 of 14]
the posterior margin. Sectioning reveals a white-tan lobulated mass abutting the mucosal surface measuring 2.0 x 1.8 x 1.8 cm. It appears to abut the inferior margin and lateral margin and extends to within 0.3 cm of the medial margin. Representative sections are submitted in 10 cassettes.

Summary of Sections:

D1 - anterior margin en face.

D2-D9 - full thickness sections with nearest margins, alternating cassettes, the first including the mucosal surface and the second the inferior margin.

D10 - posterior margin en face. Jar 1.

E. The next container is designated "posterior deep margin."

The specimen consists of a red 1.3 x 0.6 x 0.3 cm tissue fragment entirely submitted for frozen section as E1FS.

F. The next container is designated "posterior mucosa." The

specimen consists of a red-tan strip measuring 1.8 x 0.4 x 0.2 cm entirely submitted for frozen section as F1FS.

G. The next container is designated "right gingival margin."

The specimen consists of a pink-tan strip measuring 2.6 x 0.1 x 0.1 cm, entirely submitted for frozen section as G1FS.

[page 7 of 14]
H. The next container is designated "right superficial lymph node." The specimen consists of a tan-pink 1.2 x 0.5 x 0.3 cm tissue fragment entirely submitted for frozen section as H1FS.

I. The next container I is designated "right level 3 lymph node." The specimen consists of a 0.8 x 0.4 x 0.4 cm pink-tan node entirely submitted for frozen section as I1FS.

J. The next container is designated "right zone 3." The specimen consists of an irregular shaped fragment of yellow lobulated fibrofatty tissue measuring 3.8 x 2.1 x 0.9 cm. Sectioning reveals no discrete lymph nodes within the fibrofatty tissue. All of the tissue is submitted.

Summary of Sections:

J1-J3 - right zone 3 fibrofatty tissue. Jar -0.

K. The next container is designated "right level 2 neck dissection." The specimen consists of a salivary gland and three probable tan lymph nodes. The salivary gland measures 3.7 x 3.2 x 1.2 cm and the probable lymph nodes range from 0.5 to 1.6 cm in greatest dimension. The salivary gland is sectioned revealing the usual lobulated tan gross appearance. There are no discrete nodules, foci of necrosis or hemorrhage. Representative sections of the salivary gland are submitted in two cassettes. The three probable lymph nodes are

[page 8 of 14]
entirely submitted in a third cassette.

Summary of Sections:

K1-K2 - right level 2 neck dissection, salivary gland.

K3 - three probable lymph nodes. Jar 1.

L. The next container is designated "right zone 2A." The specimen consists of an irregular shaped fragment of yellow lobulated fibrofatty tissue with possible embedded lymph node measuring 3.7 x 2.0 x 1.2 cm. Sectioning reveals a homogeneous tan nodule within an embedded lymph node. The nodule measures 1.1 cm in greatest dimension. A second node also appears to be grossly positive. Representative sections are submitted in three cassettes.

Summary of Sections:

L1 - right zone 2A, probable lymph node positive for metastatic disease.

L2 - lymph node with possible metastatic disease.

L3 - fibrofatty tissue. Jar 1.

M. The next container is designated "2A-2B junction." The specimen consists of a pink-tan 0.6 x 0.5 x 0.5 cm tissue fragment bisected and entirely submitted for frozen section as M1FS.

N. The next container is designated "right zone 2." The specimen consists of a fragment of yellow lobulated fibrofatty tissue

[page 9 of 14]
measuring 3.5 x 1.6 x 7.8 cm. Six probable lymph nodes are identified within the fibrofatty tissue ranging from 0.6 to 1.6 cm in greatest dimension. The six lymph nodes are entirely submitted in two cassettes and the fibrofatty tissue is entirely submitted in a third cassette.

Summary of Sections:

N1 - right zone 2, three probable lymph nodes.

N2 - three probable lymph nodes.

N3 - fibrofatty tissue. Jar 0.

O. The next container is designated "right zone3." The specimen consists of two fragments of fibrofatty tissue with embedded lymph nodes measuring in aggregate 3.2 x 2.5 x 1.0 cm. Seven probable lymph nodes are identified within the fibrofatty tissue ranging from 0.6 to 1.6 cm in greatest dimension. The seven probable lymph nodes are entirely submitted in two cassettes.

Summary of Sections:

O1 - three right zone 3 lymph nodes.

O2 - four right zone 3 lymph nodes. Jar 1.

P. The next container is designated "PET positive left zone 3 lymph node." The specimen consists of a 1.3 x 0.7 x 0.4 cm lymph node entirely submitted for frozen section as P1FS.

[page 10 of 14]
Q. The next container is designated "left JD lymph node." The specimen consists of a tan-pink 3.0 x 1.1 x 0.9 cm lymph node. The outer surfaces are inked black for identification. The specimen is transversely sectioned and entirely submitted for frozen section in two cassettes as Q1 and Q2FS.

R. The next container is designated "right level 1B." The specimen consists of a single pink-tan lymph node measuring 1.3 x 0.7 x 0.4 cm entirely submitted as R.

S. The last container is designated "level 1A and left level 1B." The specimen consists of a 6.2 x 3.2 x 2.5 cm fragment of fibrofatty tissue with embedded salivary gland and probable embedded lymph nodes. The tan lobulated salivary gland measures 4.0 x 2.5 x 1.3 cm. Sectioning reveals lobulated tan parenchyma with focally intense hyperemia. There are no discrete nodules or foci of necrosis. Seven red-tan lymph nodes are identified within the fibrofatty tissue ranging from 0.6 to 1.4 cm in greatest dimension. Representative sections of the salivary gland are submitted in two cassettes. The seven probable lymph nodes are entirely submitted in two additional cassettes.

Summary of Sections:

S1-S2 - level 1A and left level 1B salivary gland.

S3 - six probable lymph nodes.

S4 - one probable lymph node. Jar 1.

[page 11 of 14]
Representative tissue was procured for potential future studies from specimen D.

INTRAOPERATIVE CONSULTATION:

FROZEN SECTION DIAGNOSIS:

AFS1: Anterior midline. - "Negative."

BFS1: Left lateral. - "Negative."

CFS1: Medial mucosa. - "Negative."

EFS1: Posterior deep margin. - "Negative."

FFS1: Posterior mucosa. - "Negative for dysplasia and malignancy."

GFS1: Right gingival margin. - "Negative for dysplasia and malignancy."

HFS1: Right superficial lymph node. - "Negative."

IFS1: Right zone 3. - "Negative."

MFS1: 2A/2B junction. - "Negative."

PFS1: PET positive left zone 3 lymph node. - "Negative."

QFS1: Left JD lymph node. - "Negative."

MICROSCOPIC:

Microscopic examination is performed. Permanent sections confirm the frozen section diagnoses.

LIP AND ORAL CAVITY: Resection

[page 12 of 14]
Specimen: Right tongue, NOS

Received: Fresh

Procedure: Right hemi-glossectomy

Specimen Integrity: Intact

Specimen Size: Greatest dimensions: 5.0 x 3.5 x 2.7 cm

Specimen Laterality: Right

Tumor Site: Right antero-lateral tongue

Tumor Focality: Single focus

Tumor Size: Greatest dimension: 2.0 cm, additional dimensions: 1.8 x
1.8 cm

Tumor Thickness (pT1 and pT2 tumors): Tumor thickness: 18 mm

Histologic Type: Squamous cell carcinoma, conventional

Histologic Grade: Well differentiated

[page 13 of 14]
Margins: All margins uninvolved by invasive carcinoma and in situ carcinoma

Lymph-Vascular Invasion: Not identified

Perineural Invasion: Not identified

Lymph Nodes, Extranodal Extension: Not identified

Pathologic Staging (pTNM)

Primary Tumor (pT)

pT1: Tumor 2 cm or less in greatest dimension

Regional Lymph Nodes (pN)

pN2b: Metastasis in multiple ipsilateral lymph nodes, none more than 6cm in greatest dimension

Number of Lymph Nodes Examined: 35

Number of Lymph Nodes Involved: 2

Distant Metastasis (M)

M0: Distant metastasis clinically absent

[page 14 of 14]
Additional Pathologic Findings:

Focal moderate to severe dysplasia

Source: NCI Genomic Data Commons file 8d013589-acbb-4493-8df1-a056a3a89807 (TCGA-MT-A51X.065791FC-924D-4B58-9910-D922EBFFC18B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).